TCGA case TCGA-K1-A42W — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Myomatous Neoplasms; Primary site: Retroperitoneum and peritoneum; Tissue source site: University of Pittsburgh. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/83a93378-0978-4102-9e4b-09b547b75687

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 65 years; Vital status: Alive.

Diagnoses (2)
1. Leiomyosarcoma, NOS (the primary disease): ICD-O-3 morphology code: 8890/3; ICD-10 code: C48.0; Tissue or organ of origin: Retroperitoneum; Site of resection or biopsy: Retroperitoneum; Classification of tumor: primary; Age at diagnosis: 65.5 years (23,910 days); Year of diagnosis: 2009; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor depth measurement: 3; Tumor length measurement: 3; Tumor width measurement: 3.
   Pathology details: Consistent pathology review: Yes; Margin status: Uninvolved.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 3.5; Tumor length measurement: 3.5; Tumor width measurement: 3.5.
   Pathology details: Measurement type: Pathologic; Tumor burden: 3.5.
   Pathology details: Measurement type: Radiologic; Tumor burden: 3.
2. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Liver. Age at diagnosis: 67.7 years (24,736 days); Days to diagnosis: 826 days (2.3 years); Prior treatment: Yes.

Follow-up (3 entries)
- Day 826 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 826 days (2.3 years).
- Days to follow up: 830 days (2.3 years); Disease response: With Tumor.
- Days to follow up: 1,891 days (5.2 years); Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-K1-A42W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 520 mg.
  Slide TCGA-K1-A42W-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-K1-A42W-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-K1-A42W-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology: Histologic diagnosis: Leiomyosarcoma (LMS); Histologic subtype: Conventional leiomyosarcoma; Leiomyo major vessel involvement: No Major Vessel Involvement; Margin status: Negative.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Retroperitoneum/Upper abdominal - Pancreas.
- Primary pathology, Tumor sizes, Tumor size: Lesion radiologic length: 3; Lesion radiologic width: 3; Lesion radiologic depth: 3.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome at TCGA followup: Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,891 days; disease-specific survival: no event (censored), 1,891 days; disease-free interval: event (new tumor event after initially disease-free), 826 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 826 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-K1-A42W-01A-11D-A24M-01): tumor purity 0.71, ploidy 2.81, whole-genome doublings 1.
